Somatic mutation profile of tumor specimen TCGA-ET-A2MZ-01A (aliquot TCGA-ET-A2MZ-01A-12D-A19J-08) from TCGA case TCGA-ET-A2MZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.4 years (14,408 days).
Specimen TCGA-ET-A2MZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a4a7e05-be37-443e-a7f6-2051c75a873f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A2MZ-10A (Blood Derived Normal), aliquot TCGA-ET-A2MZ-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57a76c90-db47-4003-8d3b-4cbbcaa02097

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- HAAO | c.215A>T p.H72L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.239); catalogued as COSV54313688; called by muse, mutect2, varscan2
- ZNF254 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.67); catalogued as rs1319143786, COSV60055535; called by muse, mutect2, varscan2
- SRSF11 | c.1320del p.E441Rfs*5 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- ADGRA2 | c.1935G>A p.L645= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs952648473, COSV59448164; called by muse, mutect2, varscan2
